Somatic mutation profile of tumor specimen TCGA-EE-A2GH-06A (aliquot TCGA-EE-A2GH-06A-11D-A196-08) from TCGA case TCGA-EE-A2GH, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 48.2 years (17,619 days).
Specimen TCGA-EE-A2GH-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) beaf3b41-e881-4e79-9a9b-4ac32501fefc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EE-A2GH-10A (Blood Derived Normal), aliquot TCGA-EE-A2GH-10A-01D-A198-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30aff4ed-89fd-45aa-abaa-2e28f4c1f7c5

The open-access MAF lists 373 somatic variants for this specimen: 251 protein-altering or splice-affecting, 113 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 222, Silent 113, Nonsense Mutation 17, RNA 5, Intron 4, Splice Site 3, Frame Shift Ins 2, Splice Region 2, Translation Start Site 2, Frame Shift Del 2, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ABCA8 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV52193595; called by mutect2, varscan2
- ACE | c.3451C>T p.P1151S | Missense Mutation (SNP) | VAF 13/66 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.121); catalogued as COSV52003887; called by muse, mutect2, varscan2
- ADAM2 | c.1993G>A p.A665T | Missense Mutation (SNP) | VAF 37/125 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.093); catalogued as COSV55859411; called by muse, mutect2
- ADCYAP1R1 | c.1238G>A p.R413Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs267601483, COSV58441747; called by mutect2, varscan2
- ADGRG4 | c.5993G>A p.G1998E | Missense Mutation (SNP) | VAF 34/87 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.291); catalogued as COSV54950747; called by muse, mutect2, varscan2
- AFM | c.1396G>A p.E466K | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.519); catalogued as rs926882177, COSV56919214; called by mutect2, varscan2
- AGT | c.1280G>A p.S427N | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.626); catalogued as COSV64183990; called by muse, mutect2, varscan2
- AKAP3 | c.2212C>T p.H738Y | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.026); catalogued as COSV57414426; called by muse, mutect2, varscan2
- ALDH16A1 | c.2108C>T p.A703V | Missense Mutation (SNP) | VAF 23/123 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as rs1173936187, COSV99512791; called by muse, mutect2, varscan2
- AMPD1 | c.208G>A p.E70K | Missense Mutation (SNP) | VAF 25/106 reads (24%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.573); catalogued as COSV62415188; called by muse, mutect2, varscan2
- ANKFN1 | c.577C>T p.L193F | Missense Mutation (SNP) | VAF 9/70 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59441949, COSV59454344; called by muse, mutect2, varscan2
- ANO1 | c.155G>A p.G52D | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as COSV60281754; called by muse, mutect2, varscan2
- ANO4 | c.1460G>A p.G487E (on ENST00000392977 / NM_001286615.2; = p.G452E on NM_178826.4) | Missense Mutation (SNP) | VAF 17/112 reads (15%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.926); catalogued as COSV54587402; called by muse, mutect2, varscan2
- AP4S1 | c.211G>T p.V71F | Missense Mutation (SNP) | VAF 68/432 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.521); catalogued as COSV53554568; called by muse, mutect2, varscan2
- ARHGAP24 | c.1709C>T p.S570F (on ENST00000395184 / NM_001025616.3; = p.S477F on NM_031305.3) | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV51987132; called by muse, mutect2, varscan2
- ARMC2 | c.2035G>A p.E679K | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.199); catalogued as COSV64550147; called by muse, mutect2, varscan2
- ARMC3 | c.2533G>A p.E845K | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.8); PolyPhen benign (0.015); catalogued as COSV53057880; called by muse, varscan2
- ARMC4 | c.2210G>A p.G737E | Missense Mutation (SNP) | VAF 24/142 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1473999696, COSV59457604; called by muse, mutect2, varscan2
- ASTN1 | c.727G>A p.E243K | Missense Mutation (SNP) | VAF 15/83 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); catalogued as rs764306817, COSV56061349, COSV56062610, COSV56063648; called by muse, mutect2, varscan2
- BAIAP2 | c.370C>T p.Q124* | Nonsense Mutation (SNP) | VAF 14/124 reads (11%) | catalogued as COSV58333584; called by muse, mutect2, varscan2
- BCL11A | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 72/396 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as COSV59625258; called by muse, mutect2, varscan2
- BLK | c.388G>A p.G130S | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99377085; called by muse, mutect2, varscan2
- BLK | c.389G>A p.G130D | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.099); catalogued as COSV99377087; called by muse, mutect2, varscan2
- BRAF | c.953C>T p.P318L | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as COSV56233689; called by muse, mutect2, varscan2
- BRAF | c.952C>T p.P318S | Missense Mutation (SNP) | VAF 24/126 reads (19%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV99958451; called by muse, mutect2, varscan2
- BTNL2 | c.1157G>A p.W386* | Nonsense Mutation (SNP) | VAF 21/180 reads (12%) | catalogued as COSV66630267; called by muse, mutect2, varscan2
- C16orf89 | c.503G>A p.G168E | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60122419; called by muse, mutect2, varscan2
- C8orf34 | c.1306G>A p.E436K | Missense Mutation (SNP) | VAF 8/37 reads (22%) | SIFT tolerated (0.43); PolyPhen benign (0.055); catalogued as COSV57398183; called by mutect2, varscan2
- CACNA1S | c.451C>T p.P151S | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.248); catalogued as COSV62936836; called by muse, mutect2, varscan2
- CALCR | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 15/125 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV64006150; called by muse, mutect2, varscan2
- CAMK2N1 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 6/17 reads (35%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV100906995; called by mutect2, varscan2
- CAMK2N1 | c.40C>T p.P14S | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV66757309; called by muse, mutect2, varscan2
- CARMIL1 | c.3305C>T p.P1102L | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); catalogued as COSV61514374; called by muse, mutect2, varscan2
- CASR | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.039); catalogued as COSV56134792; called by muse, mutect2, varscan2
- CCDC148 | c.1730A>T p.Q577L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.38); PolyPhen benign (0.014); catalogued as COSV51755311; called by muse, mutect2, varscan2
- CCDC80 | c.407C>T p.S136F | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV52815258; called by muse, mutect2, varscan2
- CDH20 | c.1966G>A p.E656K | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as rs758510987, COSV53004764, COSV53005466; called by muse, mutect2, varscan2
- CELF5 | c.475G>A p.V159I | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.044); catalogued as rs1455396476, COSV53010476; called by mutect2, varscan2
- CELSR1 | c.4448G>A p.G1483D | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV53082801; called by muse, mutect2, varscan2
- CELSR1 | c.4447G>A p.G1483S | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1168022499, COSV99417788; called by mutect2, varscan2
- CEP131 | c.376T>A p.W126R | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.717); catalogued as COSV53951059; called by muse, mutect2, varscan2
- CER1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.923); catalogued as COSV66602954; called by muse, mutect2, varscan2
- CFAP47 | c.1069G>A p.D357N | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.73); PolyPhen benign (0.036); catalogued as COSV52881353; called by muse, mutect2, varscan2
- CFAP54 | c.7495C>T p.P2499S | Missense Mutation (SNP) | VAF 14/62 reads (23%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as rs779717761, COSV61570918; called by muse, mutect2, varscan2
- CLEC3A | c.205G>A p.E69K (on ENST00000651443; = p.E60K on NM_005752.6) | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.137); catalogued as COSV55219916; called by muse, mutect2, varscan2
- CLSTN2 | c.1907C>T p.T636I | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as rs1416667565, COSV71718481; called by muse, varscan2
- CNTD1 | c.223C>T p.Q75* | Nonsense Mutation (SNP) | VAF 41/225 reads (18%) | catalogued as COSV59311711; called by muse, mutect2, varscan2
- CNTN5 | c.2138C>T p.S713F | Missense Mutation (SNP) | VAF 18/91 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54285848; called by muse, mutect2, varscan2
- CNTNAP2 | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.01); catalogued as rs750079255, COSV62140550; called by muse, mutect2, varscan2
- COL1A1 | c.1676C>T p.A559V | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.221); catalogued as COSV56802926; called by muse, mutect2, varscan2
- COL4A3 | c.2819G>A p.G940E | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59257562; called by muse, mutect2, varscan2
- COL7A1 | c.3621G>A p.M1207I | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.001); catalogued as COSV60391902; called by muse, mutect2, varscan2
- CPAMD8 | c.1543G>A p.E515K (on ENST00000651564; = p.E468K on NM_015692.5) | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.018); catalogued as rs773523189, COSV52231691; called by muse, mutect2, varscan2
- CR1 | c.326A>T p.D109V | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.892); catalogued as rs377658670; called by mutect2, varscan2
- CRYBG3 | c.6062C>T p.T2021I | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.361); catalogued as COSV51709855; called by mutect2, varscan2
- CSMD1 | c.3158C>T p.A1053V (on ENST00000520002; = p.A1052V on NM_033225.6) | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.848); catalogued as COSV100147411, COSV59288574; called by muse, mutect2, varscan2
- CSMD2 | c.2320G>A p.D774N | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.836); catalogued as rs867845134, COSV53881350; called by muse, mutect2, varscan2
- CTC1 | c.481C>T p.P161S | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59852300; called by muse, mutect2, varscan2
- CTSE | c.680A>G p.N227S (on ENST00000360218; = p.N222S on NM_001910.4) | Missense Mutation (SNP) | VAF 28/167 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV63059911; called by muse, varscan2
- CYLC2 | c.841G>A p.D281N | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.506); catalogued as rs777713576, COSV66336412; called by mutect2, varscan2
- CYP3A4 | c.604C>T p.P202S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as rs559410716, COSV60501108; called by muse, varscan2
- CYTIP | c.167G>A p.R56Q | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as rs752496759, COSV51632203; called by muse, mutect2, varscan2
- CYYR1 | c.211G>A p.V71I | Missense Mutation (SNP) | VAF 16/109 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV100176833; called by muse, mutect2
- DGKD | c.2263C>T p.L755= (on ENST00000264057 / NM_152879.3; = p.L711= on NM_003648.3 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 17/73 reads (23%) | catalogued as COSV51034518; called by muse, varscan2
- DMGDH | c.632C>T p.A211V | Missense Mutation (SNP) | VAF 19/119 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.074); catalogued as COSV54861057; called by muse, mutect2, varscan2
- DNAH7 | c.12075A>C p.*4025Yext*35 | Nonstop Mutation (SNP) | VAF 10/42 reads (24%) | catalogued as COSV56754067; called by muse, varscan2
- DNAH9 | c.8323G>A p.E2775K | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0.097); catalogued as rs754629782, COSV52337021; called by muse, mutect2, varscan2
- DSG4 | c.2653C>T p.P885S | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs200412706, COSV57388943; called by muse, mutect2, varscan2
- DYNAP | c.530C>T p.S177L (on ENST00000321600; = p.S151L on NM_173629.3) | Missense Mutation (SNP) | VAF 11/74 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.068); catalogued as rs1461206570, COSV58666074; called by muse, mutect2, varscan2
- DYSF | c.3341G>A p.G1114E | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.904); catalogued as COSV50273130; called by muse, mutect2
- EDNRA | c.6A>C p.E2D | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as COSV60095943; called by muse, mutect2, varscan2
- EIF4A1 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 29/186 reads (16%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV53442198, COSV99548884; called by muse, varscan2
- ELP3 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.955); catalogued as COSV56457917; called by muse, mutect2, varscan2
- EVPL | c.4348G>A p.E1450K | Missense Mutation (SNP) | VAF 22/129 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56908161; called by muse, mutect2, varscan2
- FAAH2 | c.413G>A p.G138E | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.866); catalogued as COSV66505852; called by muse, mutect2, varscan2
- FADS2 | c.994C>T p.H332Y | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.943); catalogued as COSV53897142; called by muse, varscan2
- FAM221A | c.532C>T p.Q178* | Nonsense Mutation (SNP) | VAF 24/151 reads (16%) | catalogued as COSV61387341; called by muse, mutect2, varscan2
- FANK1 | c.192G>A p.T64= | Splice Region (SNP) | VAF 32/170 reads (19%) | catalogued as COSV100904796; called by muse, varscan2
- FANK1 | c.193G>A p.G65R | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.654); catalogued as COSV100904797, COSV64156420, COSV64157287; called by muse, varscan2
- FAT3 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 82/520 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.033); catalogued as rs756001256, COSV53081676; called by muse, mutect2, varscan2
- FBLN1 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 28/169 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs751912120, COSV53044334; called by muse, varscan2
- FBXO22 | c.1079A>C p.N360T | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as COSV57616795; called by muse, mutect2, varscan2
- FGF7 | c.479G>A p.G160E | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as COSV51065559, COSV99983326, COSV99983371; called by muse, mutect2, varscan2
- FLT1 | c.842G>A p.R281Q | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as rs55687105; called by muse, mutect2, varscan2
- FNDC1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 32/151 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs372511186; called by muse, mutect2, varscan2
- GAB2 | c.1784C>T p.P595L (on ENST00000361507 / NM_080491.3; = p.P557L on NM_012296.3) | Missense Mutation (SNP) | VAF 10/73 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs866015936, COSV60866303; called by muse, varscan2
- GABRQ | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV64781024; called by muse, mutect2, varscan2
- GAL3ST3 | c.142C>T p.P48S | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.266); catalogued as rs1565081038, COSV100360809; called by muse, varscan2
- GBA3 | c.1030G>A p.D344N | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as COSV72437883; called by muse, mutect2, varscan2
- GDF5 | c.1490C>T p.S497L | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs770714017, COSV65499698; called by mutect2, varscan2
- GK2 | c.1509G>A p.W503* | Nonsense Mutation (SNP) | VAF 18/107 reads (17%) | catalogued as rs867557237, COSV100725921; called by muse, mutect2, varscan2
- GK2 | c.1508G>A p.W503* | Nonsense Mutation (SNP) | VAF 17/106 reads (16%) | catalogued as COSV100725922; called by muse, mutect2, varscan2
- GLB1L | c.547-1G>A p.X183_splice | Splice Site (SNP) | VAF 11/48 reads (23%) | catalogued as COSV55475595; called by muse, mutect2, varscan2
- GPC4 | c.740C>T p.A247V | Missense Mutation (SNP) | VAF 27/83 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63697020; called by muse, mutect2, varscan2
- GPRC6A | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 12/83 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0.049); catalogued as COSV59951829, COSV59953492; called by muse, mutect2, varscan2
- H4C4 | c.128G>T p.G43V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV61590760; called by muse, mutect2, varscan2
- HECW1 | c.2162C>T p.S721F | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV67823297; called by muse, mutect2, varscan2
- HOXA1 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.22); PolyPhen probably damaging (1); catalogued as rs777453698, COSV58029430; called by mutect2, varscan2
- HOXA1 | c.889C>T p.P297S | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.999); catalogued as rs1469483457, COSV100547349; called by muse, mutect2, varscan2
- IGF2R | c.284C>T p.S95L | Missense Mutation (SNP) | VAF 13/78 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100807225; called by muse, mutect2, varscan2
- ILDR2 | c.464G>A p.G155E | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54829050; called by muse, mutect2, varscan2
- KALRN | c.8884C>T p.R2962C (on ENST00000360013 / NM_001024660.4; = p.R1265C on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1383359664, COSV52251030; called by mutect2, varscan2
- KCNH8 | c.2909C>T p.P970L | Missense Mutation (SNP) | VAF 30/103 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.87); catalogued as COSV60457648, COSV99069487; called by muse, mutect2, varscan2
- KCNMA1 | c.2938G>A p.D980N (on ENST00000286628 / NM_001161352.2; = p.D922N on NM_002247.4) | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT tolerated (0.49); PolyPhen benign (0.131); catalogued as COSV54231253; called by muse, mutect2, varscan2
- KIR3DL2 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 36/262 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); catalogued as COSV54389803; called by muse, mutect2, varscan2
- KRTAP6-2 | c.64G>A p.G22S | Missense Mutation (SNP) | VAF 12/96 reads (13%) | PolyPhen probably damaging (0.987); catalogued as COSV58181925, COSV58181997; called by muse, varscan2
- LAMA1 | c.6191C>T p.T2064I | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.39); PolyPhen benign (0.342); catalogued as rs1291511156, COSV67532929; called by muse, mutect2, varscan2
- LAMP5 | c.560C>T p.T187I | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.376); catalogued as COSV55715242; called by muse, mutect2, varscan2
- LCTL | c.769G>A p.G257R | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58421601; called by muse, mutect2, varscan2
- LCTL | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as rs113055189, COSV58421486; called by mutect2, varscan2
- LNX2 | c.1156C>T p.R386* | Nonsense Mutation (SNP) | VAF 23/143 reads (16%) | catalogued as rs1474566166, COSV60334462; called by muse, mutect2, varscan2
- LRFN5 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53245077; called by muse, mutect2, varscan2
- LRP1 | c.5410C>T p.Q1804* | Nonsense Mutation (SNP) | VAF 4/40 reads (10%) | catalogued as rs1555185053, COSV54503425; called by mutect2, varscan2
- LRP2 | c.5637T>G p.D1879E | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV55543243, COSV55571274, COSV99788695; called by muse, mutect2, varscan2
- LRRCC1 | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 45/175 reads (26%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV64482729; called by muse, mutect2, varscan2
- MAGEA10 | c.53C>T p.S18F | Missense Mutation (SNP) | VAF 23/58 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.734); catalogued as rs866836799, COSV99726682; called by muse, mutect2, varscan2
- MAGEA3 | c.559G>A p.D187N | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT tolerated (0.15); PolyPhen benign (0.19); catalogued as rs1556826582, COSV64755846; called by muse, mutect2, varscan2
- MAGEC1 | c.1231C>T p.P411S | Missense Mutation (SNP) | VAF 58/139 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.403); catalogued as COSV53567772, COSV53568914; called by muse, mutect2, varscan2
- MAGEC1 | c.2629G>A p.E877K | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.013); catalogued as rs1368273505, COSV53568938; called by muse, mutect2, varscan2
- MED25 | c.943G>A p.G315R | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1483220422, COSV57203178; called by muse, mutect2, varscan2
- MIB1 | c.874C>T p.H292Y | Missense Mutation (SNP) | VAF 32/236 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.478); catalogued as COSV55088298; called by muse, mutect2, varscan2
- MKRN3 | c.170C>T p.P57L | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.07); catalogued as rs1566764428, COSV58808887; called by muse, mutect2, varscan2
- MLXIP | c.2120G>A p.G707E | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100038644; called by muse, mutect2
- MS4A2 | c.210G>A p.M70I | Missense Mutation (SNP) | VAF 27/254 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.011); catalogued as COSV54011848, COSV99627363; called by mutect2, varscan2
- MTHFD1 | c.2120A>T p.H707L | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99386772; called by muse, varscan2
- MUC16 | c.28001C>A p.P9334Q | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.7); catalogued as COSV67448746; called by muse, mutect2, varscan2
- MUC16 | c.21709C>T p.Q7237* | Nonsense Mutation (SNP) | VAF 34/217 reads (16%) | catalogued as COSV67448755; called by muse, mutect2, varscan2
- MUC16 | c.10026G>A p.M3342I | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1353056133, COSV67448771; called by muse, mutect2, varscan2
- MUC16 | c.4999G>A p.E1667K | Missense Mutation (SNP) | VAF 19/74 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); catalogued as COSV67448780; called by muse, mutect2, varscan2
- MYH1 | c.2611G>A p.E871K | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.02); PolyPhen benign (0.009); catalogued as rs771382343, COSV56844413; called by muse, mutect2, varscan2
- MYH10 | c.932C>T p.S311F | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.937); catalogued as COSV52595860; called by muse, mutect2, varscan2
- MYH4 | c.2782G>A p.E928K | Missense Mutation (SNP) | VAF 53/367 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV55113200; called by muse, mutect2, varscan2
- NAT2 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 21/130 reads (16%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.81); catalogued as COSV54061345; called by muse, mutect2, varscan2
- NELL1 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV54242709; called by muse, mutect2, varscan2
- NLRC4 | c.1301G>A p.R434K | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as rs1309926200, COSV100707336; called by muse, varscan2
- NPAS3 | c.328G>A p.G110R (on ENST00000356141 / NM_001164749.2; = p.G80R on NM_022123.3) | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV58073789; called by muse, mutect2, varscan2
- NPC1 | c.2276C>T p.T759I | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.596); catalogued as COSV99341150; called by muse, mutect2, varscan2
- NPSR1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.036); catalogued as COSV62197011, COSV62200166; called by muse, mutect2, varscan2
- NRF1 | c.1151C>T p.S384L | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.041); catalogued as rs1205251935, COSV56210413; called by mutect2, varscan2
- NRG2 | c.1501C>T p.P501S | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.953); catalogued as rs575275835, COSV56829962; called by muse, mutect2, varscan2
- NTF3 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.38); PolyPhen benign (0.045); catalogued as COSV58417248; called by mutect2, varscan2
- NUP58 | c.158C>T p.P53L | Missense Mutation (SNP) | VAF 17/134 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV67750968; called by muse, mutect2, varscan2
- OLFML2B | c.1447G>A p.E483K | Missense Mutation (SNP) | VAF 31/219 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.098); catalogued as COSV99668304; called by muse, mutect2, varscan2
- OPN5 | c.182G>A p.R61Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.99); catalogued as rs201533729, COSV55244422; called by muse, mutect2, varscan2
- OR1A2 | c.823A>T p.M275L | Missense Mutation (SNP) | VAF 19/155 reads (12%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.511); catalogued as COSV67936165; called by muse, mutect2, varscan2
- OR2G6 | c.455G>A p.G152D | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58573829; called by muse, mutect2, varscan2
- OR4A15 | c.102G>A p.M34I | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59033825; called by muse, mutect2, varscan2
- OR4A5 | c.155C>T p.S52F | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.046); catalogued as COSV60521700; called by muse, mutect2, varscan2
- OR4C3 | c.719C>T p.A240V | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.506); catalogued as rs777536691, COSV60584087; called by muse, mutect2, varscan2
- OR4C6 | c.532G>A p.D178N | Missense Mutation (SNP) | VAF 14/90 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as rs868600897, COSV58602718; called by mutect2, varscan2
- OR4D6 | c.689G>A p.G230E | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT tolerated (0.09); PolyPhen benign (0.367); catalogued as COSV55659065, COSV55659343; called by muse, mutect2, varscan2
- OR4K1 | c.608G>A p.S203N | Missense Mutation (SNP) | VAF 15/133 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV53459023; called by muse, varscan2
- OR4M1 | c.413G>A p.R138Q | Missense Mutation (SNP) | VAF 27/348 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.013); catalogued as rs373032779; called by muse, mutect2
- OR5AK2 | c.813G>A p.M271I | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.646); catalogued as COSV58805081; called by muse, mutect2
- OR5M10 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 12/105 reads (11%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1380619380, COSV73242261; called by mutect2, varscan2
- OR5P2 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs867989839, COSV61490019; called by muse, mutect2, varscan2
- OR6T1 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV58305844; called by muse, mutect2, varscan2
- PAGE3 | c.7G>A p.G3R | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.901); catalogued as COSV66586667; called by mutect2, varscan2
- PARP2 | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 14/129 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV51637944; called by muse, mutect2, varscan2
- PCDH9 | c.3230G>A p.G1077E (on ENST00000377865 / NM_203487.3; = p.G1043E on NM_020403.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.446); catalogued as COSV60531760; called by muse, mutect2, varscan2
- PCSK5 | c.1327G>A p.G443R | Missense Mutation (SNP) | VAF 27/125 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65084511; called by muse, mutect2, varscan2
- PDE1A | c.1053-1G>A p.X351_splice | Splice Site (SNP) | VAF 15/90 reads (17%) | catalogued as COSV59516272; called by muse, mutect2, varscan2
- PENK | c.742G>A p.E248K | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs759815705, COSV59240234; called by muse, mutect2, varscan2
- PGAP2 | c.196G>A p.A66T (on ENST00000463452 / NM_001346398.2; = p.A127T on NM_014489.4) | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs1322012443, COSV53464171; called by muse, mutect2, varscan2
- PGK2 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV59162981; called by muse, mutect2, varscan2
- PGLS | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV53113994; called by muse, mutect2, varscan2
- PHF1 | c.799A>T p.K267* | Nonsense Mutation (SNP) | VAF 28/133 reads (21%) | catalogued as COSV65702530; called by muse, mutect2, varscan2
- PIK3CG | c.1471G>A p.G491R | Missense Mutation (SNP) | VAF 17/77 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.167); catalogued as rs376127490; called by muse, mutect2, varscan2
- PKD2L2 | c.380G>A p.G127E | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51794537; called by muse, mutect2, varscan2
- PLXNB2 | c.1297C>T p.L433F | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.022); catalogued as COSV63780317; called by muse, mutect2, varscan2
- PROS1 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.451); catalogued as rs373983977, CM064172, COSV67777518; ClinVar: uncertain significance; called by mutect2, varscan2
- PTCHD4 | c.1861G>A p.E621K | Missense Mutation (SNP) | VAF 37/147 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV100260576; called by muse, mutect2, varscan2
- PTPRC | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as COSV61405678; called by muse, mutect2, varscan2
- PTPRG | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 5/43 reads (12%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.723); catalogued as rs1226700841, COSV55630902; called by muse, mutect2, varscan2
- PTPRT | c.4273G>A p.E1425K | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.752); catalogued as COSV61963692; called by muse, mutect2, varscan2
- PTPRT | c.970G>A p.E324K | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs868376470, COSV61962472; called by muse, mutect2, varscan2
- PWWP3B | c.499G>A p.D167N | Missense Mutation (SNP) | VAF 8/22 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.029); catalogued as COSV61798513; called by mutect2, varscan2
- PYHIN1 | c.220A>G p.T74A | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated (0.77); PolyPhen benign (0.017); catalogued as COSV63721517; called by muse, mutect2, varscan2
- RIT1 | c.364C>T p.R122* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as COSV64170875; called by muse, mutect2
- ROBO1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 25/116 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.38); catalogued as rs867834716, COSV71965487, COSV71968596; called by muse, mutect2, varscan2
- RP1 | c.2969G>A p.G990E | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.038); catalogued as COSV55111256; called by muse, mutect2, varscan2
- RP1L1 | c.5974G>A p.E1992K | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.021); catalogued as COSV101223152, COSV66761810; called by muse, mutect2, varscan2
- RSBN1 | c.1007C>T p.P336L | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99793108; called by muse, mutect2, varscan2
- RSPH4A | c.76G>A p.G26R | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1435825996, COSV57633827; called by muse, mutect2, varscan2
- RTF2 | c.169T>C p.Y57H | Missense Mutation (SNP) | VAF 43/246 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV50127878; called by muse, mutect2, varscan2
- RTP5 | c.811C>T p.H271Y | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as COSV58319163; called by mutect2, varscan2
- RYR2 | c.12409G>A p.E4137K | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs267598439, COSV63666259; called by mutect2, varscan2
- SAMSN1 | c.140G>A p.G47E | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.011); catalogued as COSV53468218, COSV99581055; called by muse, varscan2
- SCN9A | c.5392G>A p.E1798K (on ENST00000303354; = p.E1787K on NM_002977.3) | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.487); catalogued as COSV57601976; called by muse, mutect2, varscan2
- SCP2D1 | c.248G>A p.R83Q | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs200564762, COSV53856674; called by muse, varscan2
- SDR16C5 | c.644G>A p.G215E | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.456); catalogued as rs766522662, COSV58125600; called by muse, mutect2, varscan2
- SEPTIN12 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs768042302, COSV51615764; called by muse, mutect2, varscan2
- SERTM1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.246); catalogued as COSV59375784; called by muse, mutect2, varscan2
- SETD5 | c.1375G>T p.E459* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as COSV56708090; called by mutect2, varscan2
- SHANK2 | c.4789C>T p.L1597F | Missense Mutation (SNP) | VAF 14/102 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.043); catalogued as COSV53587723; called by muse, mutect2, varscan2
- SLC13A3 | c.927G>A p.W309* | Nonsense Mutation (SNP) | VAF 11/86 reads (13%) | catalogued as COSV99286520; called by muse, mutect2, varscan2
- SLC13A3 | c.926G>A p.W309* | Nonsense Mutation (SNP) | VAF 11/83 reads (13%) | catalogued as COSV99286522; called by mutect2, varscan2
- SLC24A3 | c.251G>A p.S84N | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.63); PolyPhen benign (0.007); catalogued as COSV60113324; called by muse, mutect2, varscan2
- SLC38A2 | c.65C>T p.S22F | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs201301091, COSV56744215; called by muse, mutect2, varscan2
- SLC9A9 | c.691G>C p.D231H | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.964); catalogued as COSV57219691; called by muse, mutect2
- SLCO6A1 | c.40G>A p.E14K | Missense Mutation (SNP) | VAF 28/141 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.017); catalogued as COSV65806159, COSV65808257; called by muse, mutect2, varscan2
- SLFN11 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 24/124 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.4); catalogued as rs1458829699, COSV57697801; called by muse, mutect2, varscan2
- SLX4IP | c.916G>A p.D306N | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.067); catalogued as rs746954207, COSV57944495; called by muse, mutect2, varscan2
- SMAD1 | c.649C>T p.Q217* | Nonsense Mutation (SNP) | VAF 21/74 reads (28%) | catalogued as COSV57470350; called by muse, mutect2, varscan2
- SMIM21 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 25/182 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.065); catalogued as COSV66894606; called by muse, mutect2, varscan2
- SPAM1 | c.640C>T p.H214Y | Missense Mutation (SNP) | VAF 20/104 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.065); catalogued as COSV56141398; called by muse, mutect2, varscan2
- SPRR2F | c.31C>T p.P11S | Missense Mutation (SNP) | VAF 18/146 reads (12%) | PolyPhen possibly damaging (0.529); catalogued as rs1428359152, COSV100907558; called by muse, varscan2
- SPTB | c.4801G>A p.G1601S | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV67630172; called by muse, mutect2, varscan2
- SRGAP3 | c.2506C>T p.Q836* | Nonsense Mutation (SNP) | VAF 11/43 reads (26%) | catalogued as COSV64530988; called by muse, mutect2, varscan2
- SYNE1 | c.10145G>A p.S3382N (on ENST00000367255 / NM_182961.4; = p.S3389N on NM_033071.3) | Missense Mutation (SNP) | VAF 8/110 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54920029; called by muse, mutect2
- TCEAL5 | c.595G>A p.D199N | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.195); catalogued as COSV65502755, COSV65503527; called by muse, mutect2, varscan2
- THBS1 | c.2254-1G>A p.X752_splice | Splice Site (SNP) | VAF 12/88 reads (14%) | catalogued as COSV52950362; called by muse, varscan2
- THSD7A | c.3722G>A p.G1241E | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101439740; called by muse, mutect2, varscan2
- TLL1 | c.1573G>A p.G525R | Missense Mutation (SNP) | VAF 18/94 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV50263145; called by muse, varscan2
- TM4SF5 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.001); catalogued as COSV54495891; called by mutect2, varscan2
- TMC6 | c.1034C>T p.S345F | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59810674; called by muse, mutect2
- TMCO5A | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT tolerated (0.17); PolyPhen benign (0.078); catalogued as rs948996340, COSV60464134; called by muse, mutect2, varscan2
- TMEM132B | c.230G>A p.R77Q | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT tolerated (0.38); PolyPhen benign (0.021); catalogued as rs936695274, COSV54746271; called by muse, mutect2, varscan2
- TNPO3 | c.607C>T p.R203C | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as rs1403691073, COSV55278362; called by muse, mutect2, varscan2
- TRAV12-3 | c.19G>A p.V7I | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs764050611; called by muse, mutect2, varscan2
- TRIM60 | c.863G>A p.R288K | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.009); catalogued as COSV104417670, COSV61969898; called by muse, mutect2, varscan2
- TSPAN16 | c.19C>T p.P7S | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.014); catalogued as rs1193286226, COSV57441571; called by muse, mutect2, varscan2
- TSSC4 | c.13G>A p.G5R | Missense Mutation (SNP) | VAF 19/152 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV99329974; called by muse, mutect2
- TSSC4 | c.14G>A p.G5E | Missense Mutation (SNP) | VAF 20/155 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.024); catalogued as rs1203644435, COSV99329976; called by muse, mutect2
- TTLL5 | c.451C>T p.H151Y | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as COSV54028853; called by muse, mutect2, varscan2
- TTN | c.39848G>C p.C13283S (on ENST00000591111; = p.C5859S on NM_003319.4) | Missense Mutation (SNP) | VAF 17/124 reads (14%) | PolyPhen probably damaging (0.996); catalogued as COSV59911717; called by muse, mutect2, varscan2
- TTN | c.13655C>T p.A4552V (on ENST00000591111; = p.A3625V on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/54 reads (13%) | PolyPhen benign (0.41); catalogued as COSV59911745; called by muse, mutect2, varscan2
- TTN | c.12170G>A p.G4057E (on ENST00000591111; = p.G4011E on NM_003319.4) | Missense Mutation (SNP) | VAF 13/66 reads (20%) | catalogued as COSV60169984; called by muse, mutect2, varscan2
- UBASH3A | c.647G>A p.S216N | Missense Mutation (SNP) | VAF 13/75 reads (17%) | SIFT tolerated (0.55); PolyPhen benign (0.051); catalogued as rs754490856, COSV52310845; called by muse, mutect2, varscan2
- UNC5D | c.161C>G p.P54R | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99774306; called by muse, varscan2
- VPS13A | c.3176C>T p.S1059L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.597); catalogued as rs753800803, COSV62425806; called by mutect2, varscan2
- VSIG2 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs372244982; called by muse, mutect2, varscan2
- WRAP53 | c.929G>A p.R310Q | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs764895538, COSV56832880; called by mutect2, varscan2
- XYLT1 | c.1487T>A p.F496Y | Missense Mutation (SNP) | VAF 23/156 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV54478713; called by muse, mutect2, varscan2
- ZAN | c.3151G>A p.E1051K | Missense Mutation (SNP) | VAF 21/132 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.268); catalogued as rs368072574, COSV61804642; called by muse, mutect2, varscan2
- ZBTB39 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 15/96 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV55628053; called by muse, varscan2
- ZC2HC1A | c.734C>T p.P245L | Missense Mutation (SNP) | VAF 34/148 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.864); catalogued as COSV55667350; called by muse, mutect2, varscan2
- ZNF14 | c.1807C>T p.R603* | Nonsense Mutation (SNP) | VAF 17/75 reads (23%) | catalogued as rs757216310, COSV59848538; called by muse, mutect2, varscan2
- ZNF200 | c.737G>A p.R246Q | Missense Mutation (SNP) | VAF 20/116 reads (17%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs772715804, COSV67723619; called by muse, varscan2
- ZNF217 | c.1015G>A p.G339S | Missense Mutation (SNP) | VAF 13/127 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs756695641, COSV56594499; called by muse, mutect2, varscan2
- ZNF536 | c.2182G>A p.E728K | Missense Mutation (SNP) | VAF 25/199 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.551); catalogued as rs770607077, COSV62819518, COSV62833435; called by muse, mutect2, varscan2
- ZNF570 | c.1451C>T p.S484F | Missense Mutation (SNP) | VAF 10/81 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.826); catalogued as COSV57578200; called by muse, mutect2, varscan2
- ZNF705A | c.475C>T p.P159S | Missense Mutation (SNP) | VAF 32/216 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.049); catalogued as COSV63732880; called by muse, mutect2, varscan2
- ZNF98 | c.1429C>T p.L477F | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.816); catalogued as COSV63334989; called by mutect2, varscan2
- CEP250 | c.1044_1050del p.I348Mfs*10 | Frame Shift Del (DEL) | VAF 15/118 reads (13%) | called by mutect2, pindel
- IGKV6D-21 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.503); called by mutect2, varscan2
- LARP4B | c.1338del p.N447Mfs*45 | Frame Shift Del (DEL) | VAF 29/191 reads (15%) | called by mutect2, pindel, varscan2
- PIGW | c.1154T>C p.L385P | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PNRC2 | c.313dup p.S105Kfs*16 | Frame Shift Ins (INS) | VAF 12/89 reads (13%) | called by mutect2, pindel, varscan2
- TCEAL6 | c.525dup p.G176Rfs*26 | Frame Shift Ins (INS) | VAF 4/38 reads (11%) | called by pindel, varscan2
- ABCD4 | c.882C>T p.F294= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as COSV53991009; called by mutect2, varscan2
- ACTBL2 | c.456C>T p.I152= | Silent (SNP) | VAF 18/60 reads (30%) | catalogued as COSV70661035; called by muse, mutect2, varscan2
- ADAM18 | c.1965C>T p.F655= | Silent (SNP) | VAF 18/197 reads (9%) | catalogued as COSV55843213; called by muse, mutect2, varscan2
- ADAMDEC1 | c.870C>T p.F290= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV99835988; called by muse, mutect2, varscan2
- ADCY8 | c.2391C>T p.F797= | Silent (SNP) | VAF 20/47 reads (43%) | catalogued as rs267601771, COSV53897529, COSV99654296; called by muse, mutect2, varscan2
- ADCY8 | c.669G>A p.E223= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV53897986; called by muse, mutect2, varscan2
- ALDH16A1 | c.2109C>T p.A703= | Silent (SNP) | VAF 23/123 reads (19%) | catalogued as COSV99512794; called by muse, mutect2, varscan2
- ANK3 | c.9648C>T p.T3216= | Silent (SNP) | VAF 28/136 reads (21%) | catalogued as COSV55046778; called by muse, mutect2, varscan2
- ANKRD44 | c.1062G>A p.L354= | Silent (SNP) | VAF 16/83 reads (19%) | catalogued as COSV56550279; called by muse, mutect2, varscan2
- APOH | c.408C>T p.V136= | Silent (SNP) | VAF 14/98 reads (14%) | catalogued as rs770893310, COSV52771622; called by muse, mutect2, varscan2
- BAIAP2L2 | c.318G>A p.K106= | Silent (SNP) | VAF 12/93 reads (13%) | catalogued as COSV60201432; called by muse, mutect2, varscan2
- BBX | c.1056G>A p.K352= | Silent (SNP) | VAF 47/203 reads (23%) | catalogued as COSV57879929; called by muse, mutect2, varscan2
- BRINP3 | c.2223G>A p.R741= | Silent (SNP) | VAF 21/111 reads (19%) | catalogued as rs748787449, COSV66514860; called by muse, mutect2, varscan2
- BTAF1 | c.3061C>T p.L1021= | Silent (SNP) | VAF 8/45 reads (18%) | catalogued as COSV56430494; called by muse, varscan2
- CABIN1 | c.3726C>T p.A1242= | Silent (SNP) | VAF 10/79 reads (13%) | catalogued as rs753038615, COSV54078448; called by muse, mutect2, varscan2
- CACNG4 | c.387G>A p.R129= | Silent (SNP) | VAF 11/85 reads (13%) | catalogued as COSV50924246; called by muse, mutect2, varscan2
- CASS4 | c.2004G>A p.R668= | Silent (SNP) | VAF 8/75 reads (11%) | catalogued as COSV64385523; called by muse, mutect2
- CD84 | c.519A>G p.E173= | Silent (SNP) | VAF 16/102 reads (16%) | catalogued as COSV60867047; called by muse, mutect2, varscan2
- CDC27 | c.2214C>T p.L738= | Silent (SNP) | VAF 14/118 reads (12%) | catalogued as rs753974642, COSV50366999; called by mutect2, varscan2
- CFAP251 | c.1818G>A p.K606= | Silent (SNP) | VAF 16/118 reads (14%) | catalogued as rs1235673996, COSV56608526; called by muse, mutect2, varscan2
- CLEC1A | c.726G>A p.G242= | Silent (SNP) | VAF 43/236 reads (18%) | catalogued as COSV59531085; called by muse, mutect2, varscan2
- COBL | c.1785G>A p.E595= | Silent (SNP) | VAF 10/49 reads (20%) | catalogued as COSV54339636; called by muse, mutect2, varscan2
- COL1A1 | c.1677C>T p.A559= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs755073295, COSV56806154; called by mutect2, varscan2
- CPNE5 | c.471C>T p.V157= | Silent (SNP) | VAF 15/73 reads (21%) | catalogued as rs747157932, COSV55194989; called by muse, mutect2, varscan2
- CYB5R4 | c.1548C>T p.I516= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV63750251; called by muse, mutect2
- DDC | c.171C>T p.I57= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV63564020; called by mutect2, varscan2
- DEPDC1 | c.309C>T p.L103= | Silent (SNP) | VAF 4/38 reads (11%) | catalogued as COSV63957601; called by muse, mutect2
- DMXL2 | c.4057T>C p.L1353= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV51841556; called by muse, mutect2, varscan2
- DNAH7 | c.11982G>A p.T3994= | Silent (SNP) | VAF 12/52 reads (23%) | catalogued as rs781492764, COSV56753497; called by muse, varscan2
- DPY19L3 | c.1347G>C p.V449= | Silent (SNP) | VAF 9/66 reads (14%) | catalogued as COSV60474913; called by muse, mutect2, varscan2
- DSCAM | c.5841G>A p.P1947= | Silent (SNP) | VAF 10/44 reads (23%) | catalogued as rs754261783, COSV68021904; called by mutect2, varscan2
- ECPAS | c.1734C>T p.V578= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as rs772077211, COSV52192687; called by mutect2, varscan2
- EDC3 | c.699C>T p.S233= | Silent (SNP) | VAF 16/101 reads (16%) | catalogued as COSV59339282; called by muse, mutect2, varscan2
- EGFLAM | c.2013G>A p.V671= | Silent (SNP) | VAF 32/164 reads (20%) | catalogued as COSV59294277; called by muse, mutect2, varscan2
- ENTPD2 | c.579G>A p.R193= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV57074698; called by mutect2, varscan2
- EPPK1 | c.5187C>T p.F1729= | Silent (SNP) | VAF 22/66 reads (33%) | catalogued as rs781920013, COSV73260850; called by mutect2, varscan2
- FPGT | c.504C>T p.P168= | Silent (SNP) | VAF 23/124 reads (19%) | catalogued as COSV100907137; called by muse, mutect2, varscan2
- GLRB | c.1386G>A p.A462= | Silent (SNP) | VAF 20/103 reads (19%) | catalogued as rs771819827, COSV52413712; called by muse, mutect2, varscan2
- HECA | c.1029C>T p.F343= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV62768520; called by muse, mutect2, varscan2
- HELZ2 | c.6342C>T p.S2114= (on ENST00000467148 / NM_001037335.2; = p.S1545= on NM_033405.3) | Silent (SNP) | VAF 4/11 reads (36%) | catalogued as COSV71295493; called by muse, mutect2, varscan2
- HEPH | c.1080C>T p.L360= (on ENST00000343002; = p.L93= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 11/31 reads (35%) | catalogued as COSV100295848, COSV57959985; called by muse, mutect2, varscan2
- HLA-DQA2 | c.294C>T p.F98= | Silent (SNP) | VAF 17/158 reads (11%) | catalogued as COSV100890704, COSV66566059; called by muse, varscan2
- HMMR | c.1884A>G p.L628= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV62373973; called by muse, mutect2, varscan2
- HOOK2 | c.1890C>T p.S630= | Silent (SNP) | VAF 9/51 reads (18%) | catalogued as COSV53401494; called by muse, mutect2, varscan2
- IGHV7-81 | c.111G>A p.V37= | Silent (SNP) | VAF 19/119 reads (16%) | called by muse, mutect2, varscan2
- ITGA3 | c.1695C>T p.L565= | Silent (SNP) | VAF 10/98 reads (10%) | catalogued as COSV50306360; called by mutect2, varscan2
- KRTAP23-1 | c.186G>A p.L62= | Silent (SNP) | VAF 6/47 reads (13%) | called by mutect2, varscan2
- MACF1 | c.9333C>T p.T3111= | Silent (SNP) | VAF 15/74 reads (20%) | catalogued as COSV57109190; called by muse, mutect2, varscan2
- MAGEB16 | c.726C>T p.I242= | Silent (SNP) | VAF 11/36 reads (31%) | catalogued as COSV67873599; called by muse, mutect2, varscan2
- MAGEC1 | c.2202G>A p.E734= | Silent (SNP) | VAF 32/109 reads (29%) | catalogued as rs1198534420, COSV53568922; called by muse, mutect2, varscan2
- MECOM | c.300C>T p.I100= | Silent (SNP) | VAF 12/110 reads (11%) | catalogued as rs142755875; called by mutect2, varscan2
- MICAL2 | c.1770C>T p.I590= | Silent (SNP) | VAF 22/160 reads (14%) | catalogued as COSV56317164; called by muse, mutect2, varscan2
- MLXIP | c.2121G>A p.G707= | Silent (SNP) | VAF 19/87 reads (22%) | catalogued as COSV100038647; called by muse, mutect2, varscan2
- MXRA5 | c.5250G>A p.Q1750= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV54225648; called by muse, varscan2
- MYBPH | c.471C>T p.A157= | Silent (SNP) | VAF 7/54 reads (13%) | catalogued as COSV55137272; called by mutect2, varscan2
- MYH1 | c.4353G>A p.R1451= | Silent (SNP) | VAF 15/97 reads (15%) | catalogued as COSV56844405; called by muse, mutect2, varscan2
- MYH14 | c.3036C>T p.S1012= | Silent (SNP) | VAF 4/14 reads (29%) | catalogued as COSV51811405; called by muse, mutect2, varscan2
- NLRC4 | c.1302G>A p.R434= | Silent (SNP) | VAF 10/46 reads (22%) | catalogued as COSV100707335; called by muse, varscan2
- NLRP1 | c.2094G>A p.R698= | Silent (SNP) | VAF 13/70 reads (19%) | catalogued as COSV52558713; called by muse, mutect2, varscan2
- NLRP4 | c.1800G>A p.R600= | Silent (SNP) | VAF 10/75 reads (13%) | catalogued as COSV100016098; called by muse, mutect2, varscan2
- NOD1 | c.849C>T p.F283= | Silent (SNP) | VAF 16/56 reads (29%) | catalogued as rs775038461, COSV56111035; called by muse, mutect2, varscan2
- NOMO3 | c.1332C>T p.T444= | Silent (SNP) | VAF 25/149 reads (17%) | catalogued as rs531218580, COSV53769457; called by muse, mutect2, varscan2
- NPC1 | c.2277C>T p.T759= | Silent (SNP) | VAF 16/50 reads (32%) | catalogued as COSV99341145; called by muse, mutect2, varscan2
- NTNG1 | c.453C>T p.T151= | Silent (SNP) | VAF 14/81 reads (17%) | catalogued as COSV53964325, COSV99634818; called by muse, mutect2, varscan2
- NYNRIN | c.3162C>T p.I1054= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as rs1052949659, COSV66841326; called by mutect2, varscan2
- OR10Q1 | c.537C>T p.I179= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as rs1260344950, COSV57469847; called by mutect2, varscan2
- OR2M4 | c.771C>T p.F257= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs767136745, COSV60707409; called by mutect2, varscan2
- OR2T2 | c.339C>T p.F113= | Silent (SNP) | VAF 14/142 reads (10%) | catalogued as COSV61617737, COSV61618215; called by muse, mutect2
- OR4C46 | c.252C>T p.L84= | Silent (SNP) | VAF 19/150 reads (13%) | catalogued as COSV60218482; called by muse, mutect2, varscan2
- OR4K5 | c.768C>T p.F256= | Silent (SNP) | VAF 30/270 reads (11%) | catalogued as rs865910370, COSV60002532; called by muse, mutect2, varscan2
- OR4X2 | c.555C>T p.F185= | Silent (SNP) | VAF 38/243 reads (16%) | catalogued as COSV56582247; called by muse, mutect2, varscan2
- OR52A1 | c.690T>A p.R230= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV61092038; called by muse, mutect2, varscan2
- OR5B12 | c.453C>T p.F151= | Silent (SNP) | VAF 15/120 reads (13%) | catalogued as rs1201627555, COSV56904145; called by muse, mutect2, varscan2
- OR5F1 | c.531C>T p.F177= | Silent (SNP) | VAF 15/128 reads (12%) | catalogued as COSV53545459, COSV53546047; called by muse, mutect2, varscan2
- OR6N2 | c.615C>T p.F205= | Silent (SNP) | VAF 8/42 reads (19%) | catalogued as COSV59410516; called by mutect2, varscan2
- OR8I2 | c.42C>T p.L14= | Silent (SNP) | VAF 26/181 reads (14%) | catalogued as COSV56166774; called by muse, mutect2, varscan2
- PCF11 | c.180C>T p.A60= | Silent (SNP) | VAF 12/130 reads (9%) | catalogued as COSV53528174; called by muse, mutect2
- PDE1B | c.1542C>T p.S514= | Silent (SNP) | VAF 15/125 reads (12%) | catalogued as COSV54490011; called by muse, mutect2, varscan2
- PNMA5 | c.471G>A p.R157= | Silent (SNP) | VAF 40/108 reads (37%) | catalogued as rs1556924465, COSV62625308; called by muse, mutect2, varscan2
- PRRT2 | c.864C>T p.F288= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs1359563519, COSV54881666; called by mutect2, varscan2
- PSG3 | c.219G>A p.K73= | Silent (SNP) | VAF 45/248 reads (18%) | catalogued as rs150813172; called by muse, mutect2, varscan2
- PXDNL | c.1671C>T p.F557= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV62480087, COSV62480761; called by muse, mutect2, varscan2
- QSER1 | c.1497C>A p.S499= (on ENST00000399302; = p.S628= on NM_001076786.3) | Silent (SNP) | VAF 16/80 reads (20%) | catalogued as COSV67899683; called by muse, mutect2, varscan2
- RDH10 | c.873C>T p.R291= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as COSV53581447; called by muse, mutect2, varscan2
- RET | c.3183C>T p.L1061= | Silent (SNP) | VAF 4/16 reads (25%) | catalogued as COSV60687956; called by muse, mutect2
- RNF17 | c.1455C>T p.I485= | Silent (SNP) | VAF 22/204 reads (11%) | catalogued as COSV55035071; called by muse, mutect2
- SERPINA9 | c.1242C>A p.P414= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV54073031; called by muse, mutect2, varscan2
- SIGLEC11 | c.2034C>T p.P678= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs1300200443, COSV68567512; called by muse, mutect2
- SIPA1L2 | c.390C>T p.L130= | Silent (SNP) | VAF 20/153 reads (13%) | catalogued as rs373470985, COSV53384531; called by muse, mutect2, varscan2
- SLC24A2 | c.1317C>T p.L439= | Silent (SNP) | VAF 9/76 reads (12%) | catalogued as COSV53858630; called by muse, mutect2, varscan2
- SLC25A41 | c.286C>T p.L96= | Silent (SNP) | VAF 9/46 reads (20%) | catalogued as COSV51190561, COSV51190851; called by muse, mutect2, varscan2
- SLC5A10 | c.153C>T p.F51= | Silent (SNP) | VAF 12/78 reads (15%) | catalogued as COSV58755706; called by muse, varscan2
- STAC3 | c.42C>T p.F14= | Silent (SNP) | VAF 8/60 reads (13%) | catalogued as COSV60413626; called by mutect2, varscan2
- SULT1C3 | c.657C>T p.F219= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs150872787, COSV61252494; called by muse, mutect2, varscan2
- SUMF2 | c.171C>T p.F57= (on ENST00000652303; = p.F38= on NM_015411.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV51905564; called by muse, mutect2, varscan2
- SUMF2 | c.172C>T p.L58= (on ENST00000652303; = p.L39= on NM_015411.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV99303382, COSV99303668; called by muse, mutect2, varscan2
- SYNCRIP | c.1551C>T p.P517= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as rs1336303438, COSV62286875; called by muse, mutect2, varscan2
- TG | c.7734G>A p.R2578= | Silent (SNP) | VAF 8/17 reads (47%) | catalogued as COSV55066803; called by muse, mutect2, varscan2
- THADA | c.156C>T p.I52= | Silent (SNP) | VAF 42/288 reads (15%) | catalogued as COSV67088161; called by muse, mutect2
- TMEM145 | c.558C>T p.F186= | Silent (SNP) | VAF 10/66 reads (15%) | catalogued as COSV56623939; called by mutect2, varscan2
- TNS3 | c.3666G>C p.L1222= | Silent (SNP) | VAF 18/130 reads (14%) | catalogued as COSV60787496; called by muse, varscan2
- TRAV10 | c.102C>T p.I34= | Silent (SNP) | VAF 9/68 reads (13%) | called by muse, mutect2, varscan2
- TRIML1 | c.897C>T p.L299= | Silent (SNP) | VAF 24/176 reads (14%) | catalogued as rs201972598, COSV60193494, COSV60195535; called by muse, varscan2
- TRO | c.3153C>T p.G1051= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV51498323; called by muse, mutect2, varscan2
- TSHZ3 | c.2635C>T p.L879= | Silent (SNP) | VAF 13/48 reads (27%) | catalogued as COSV53665585; called by muse, mutect2, varscan2
- TTC29 | c.504G>A p.K168= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV57272223; called by muse, mutect2, varscan2
- TTLL9 | c.138C>T p.F46= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as COSV60590018; called by muse, mutect2, varscan2
- UBAC2 | c.444C>T p.V148= (on ENST00000403766 / NM_001144072.2; = p.V113= on NM_177967.4) | Silent (SNP) | VAF 27/166 reads (16%) | catalogued as COSV63117166; called by muse, mutect2, varscan2
- VWA7 | c.2274C>T p.D758= | Silent (SNP) | VAF 38/230 reads (17%) | catalogued as rs767028933, COSV65172593; called by muse, mutect2, varscan2
- WNT10B | c.990G>A p.R330= | Silent (SNP) | VAF 6/44 reads (14%) | catalogued as COSV99975894; called by mutect2, varscan2
- ZDBF2 | c.963C>T p.I321= | Silent (SNP) | VAF 16/71 reads (23%) | catalogued as COSV65622589; called by muse, mutect2, varscan2
- ZFAND3 | c.183C>T p.S61= | Silent (SNP) | VAF 12/62 reads (19%) | catalogued as rs768288619, COSV54721523; called by muse, mutect2, varscan2
- ZNF225 | c.1722G>A p.G574= | Silent (SNP) | VAF 11/71 reads (15%) | catalogued as rs1450109262, COSV53470979; called by muse, mutect2, varscan2
- AGAP7P | n.299G>A | RNA (SNP) | VAF 14/177 reads (8%) | catalogued as rs1554938305; called by muse, varscan2
- CACNB2 | c.804+149G>A | Intron (SNP) | VAF 13/90 reads (14%) | catalogued as COSV99993981; called by muse, mutect2, varscan2
- GCNT2 | c.926-34484C>T | Intron (SNP) | VAF 22/88 reads (25%) | catalogued as rs1228519266, COSV99399198; called by muse, varscan2
- HMGB1P1 | n.173G>A | RNA (SNP) | VAF 28/174 reads (16%) | catalogued as rs1320472377; called by muse, mutect2, varscan2
- KIR3DX1 | n.753C>T | RNA (SNP) | VAF 16/71 reads (23%) | catalogued as COSV55597060, COSV99683097; called by muse, mutect2, varscan2
- MIR517B | n.45C>T | RNA (SNP) | VAF 28/126 reads (22%) | called by muse, mutect2, varscan2
- OR2U1P | n.147G>A | RNA (SNP) | VAF 36/148 reads (24%) | catalogued as rs1344411833; called by muse, mutect2, varscan2
- TTN | c.10360+4298C>T | Intron (SNP) | VAF 30/111 reads (27%) | catalogued as COSV60071976; called by muse, mutect2, varscan2
- TTN | c.10360+1987G>A | Intron (SNP) | VAF 21/80 reads (26%) | catalogued as rs868633339, COSV100605532; called by muse, mutect2, varscan2
